Gene-level copy-number profile of tumor specimen TCGA-AX-A3GB-01A from TCGA case TCGA-AX-A3GB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.2 years (26,724 days).
Specimen TCGA-AX-A3GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.78ea41b9-d537-46ae-bb86-da7be0b3f686.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3GB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0376d274-18e8-45e6-8884-1261f40f46df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 57,202; copy number 3: 14; copy number 4: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A3GB-01A-11D-A227-01): tumor purity 0.52, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
